Somatic mutation profile of tumor specimen TCGA-AX-A2HJ-01A (aliquot TCGA-AX-A2HJ-01A-11D-A17D-09) from TCGA case TCGA-AX-A2HJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 35.9 years (13,112 days).
Specimen TCGA-AX-A2HJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ec47f36-7b81-45a6-84de-258bb07c7ed5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2HJ-10A (Blood Derived Normal), aliquot TCGA-AX-A2HJ-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a34c7bfa-9a11-4974-812f-dc682482d39b

The open-access MAF lists 1,938 somatic variants for this specimen: 1,447 protein-altering or splice-affecting, 443 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,057, Silent 443, Frame Shift Del 240, Frame Shift Ins 46, Nonsense Mutation 39, Splice Site 37, Intron 19, Splice Region 15, In Frame Del 9, 3'Flank 8, RNA 7, 5'Flank 6.

Variants (750 of 1,938; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.4221del p.K1407Nfs*8 | Frame Shift Del (DEL) | VAF 22/46 reads (48%) | catalogued as rs786204655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTNND2 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as rs886041494, COSV100481426; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DCDC2 | c.529del p.I177Sfs*3 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs904944428; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 28/55 reads (51%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GCDH | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs121434366, CM920303, COSV99536200; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJB6 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28937872, CM002606, COSV53832929; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 34/76 reads (45%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KMT2B | c.3325del p.R1109Efs*73 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | catalogued as rs1555729827, COSV55857298; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- LMNA | c.1126T>C p.Y376H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1131691263, CM123362, COSV100738869; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 30/36 reads (83%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- MFRP | chr11:119345563 del G | 5'Flank (DEL) | VAF 13/46 reads (28%) | catalogued as rs587776596, CD052468, COSV64129114; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- MYO7A | c.6551C>T p.T2184M | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1383147250, CM165947, COSV60023826; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 24/67 reads (36%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PANK2 | c.1257del p.F419Lfs*31 (on ENST00000316562 / NM_153638.3; = p.F128Lfs*31 on NM_024960.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs1568574931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 18/58 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.254-2A>T p.X85_splice | Splice Site (SNP) | VAF 21/58 reads (36%) | hotspot (GDC flag); catalogued as COSV100911416, COSV64300109; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- PTPN11 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121918468, CM043335, CM096577, COSV100692090, COSV61005148; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RECQL | c.120del p.V41Sfs*2 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs745659712, COSV59084411; ClinVar: pathogenic; called by mutect2, varscan2
- SATB2 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057518190, COSV53480467, COSV99611466; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SURF1 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782024654, CM096024, COSV100034877; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+2T>C p.X187_splice | Splice Site (SNP) | VAF 19/37 reads (51%) | hotspot (GDC flag); catalogued as CS114004, COSV52709511, COSV52900265, COSV53486980, COSV99478821; called by muse, mutect2, varscan2
- AATF | c.1416A>G p.I472M | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748206822; called by muse, mutect2, varscan2
- ABCA13 | c.11708G>A p.G3903D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV101447257; called by muse, mutect2, varscan2
- ABCA4 | c.5690A>G p.Q1897R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100933293; called by muse, mutect2, varscan2
- ABCB5 | c.1492G>A p.A498T (on ENST00000404938 / NM_001163941.2; = p.A53T on NM_178559.6) | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.25); PolyPhen benign (0.331); catalogued as COSV99329913; called by muse, mutect2, varscan2
- ABCC11 | c.2486A>G p.Y829C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs1177181294, COSV62322232; called by muse, mutect2, varscan2
- ABCC2 | c.890dup p.K298Efs*36 | Frame Shift Ins (INS) | VAF 14/28 reads (50%) | catalogued as rs759781877; called by mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCD1 | c.1816T>C p.S606P | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs201774661, CM960043, COSV54383418; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ABHD11 | c.653A>G p.H218R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99766957; called by muse, mutect2, varscan2
- ABHD17A | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1376475305, COSV99171397; called by muse, mutect2, varscan2
- ABLIM2 | c.1000T>C p.S334P | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV99590629; called by muse, mutect2, varscan2
- ABRA | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs144057540, COSV100357669; called by muse, mutect2, varscan2
- AC131160.1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as rs749633030, COSV57701998; called by muse, mutect2, varscan2
- ACAD10 | c.2464G>A p.G822S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs143673663; called by muse, mutect2, varscan2
- ACAN | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100719370; called by muse, mutect2
- ACE | c.3316A>G p.R1106G | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99327759; called by muse, mutect2, varscan2
- ACSS2 | c.735A>C p.R245S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV99490250; called by muse, mutect2, varscan2
- ACTL10 | c.344G>A p.C115Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV99865203; called by muse, mutect2, varscan2
- ACTN1 | c.2407C>T p.R803C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1037154091, COSV99518602, COSV99518683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR1A | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs750233235, COSV64024212; called by muse, mutect2, varscan2
- ACVR1 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99718168; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACYP2 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1205865310, COSV100336914; called by muse, mutect2, varscan2
- ADAD2 | c.995G>A p.R332H (on ENST00000315906 / NM_001145400.2; = p.R414H on NM_139174.4) | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs371012828; called by muse, mutect2, varscan2
- ADAM11 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99567857; called by muse, mutect2, varscan2
- ADAM22 | c.1816A>G p.T606A | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs757784507, COSV99718476; called by muse, mutect2, varscan2
- ADAM9 | c.1202G>A p.C401Y | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101166287; called by muse, varscan2
- ADAMTS18 | c.2141T>C p.V714A | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV99274400; called by muse, mutect2, varscan2
- ADAMTS2 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as rs777752024, COSV51104012, COSV99205772; called by muse, mutect2, varscan2
- ADAMTS20 | c.1141T>C p.C381R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101240466; called by muse, mutect2, varscan2
- ADAMTSL1 | c.860G>C p.S287T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV99445082; called by muse, mutect2, varscan2
- ADAMTSL4 | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV99648065; called by muse, mutect2, varscan2
- ADAP2 | c.493T>C p.Y165H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972400461, COSV100437376; called by muse, mutect2, varscan2
- ADAR | c.2787A>T p.K929N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99426813; called by muse, mutect2
- ADAR | c.990A>G p.I330M | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV99426815; called by muse, mutect2, varscan2
- ADCK2 | c.535T>C p.W179R | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV99301893; called by muse, mutect2, varscan2
- ADCY10 | c.4364T>C p.M1455T | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1175554715, COSV100897109; called by muse, mutect2, varscan2
- ADGRA2 | c.1573dup p.A525Gfs*59 | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | catalogued as rs760256806; called by mutect2, varscan2
- ADGRE2 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV100216552; called by muse, mutect2
- ADGRL3 | c.2732A>G p.N911S (on ENST00000506720 / NM_001322402.2; = p.N843S on NM_015236.6) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101547411; called by muse, mutect2, varscan2
- ADRA1A | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99372419; called by muse, mutect2, varscan2
- AFF2 | c.3692G>A p.G1231D | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54001234, COSV99666545; called by muse, mutect2, varscan2
- AFP | c.1459A>G p.R487G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99890433; called by muse, mutect2, varscan2
- AGBL5 | c.1649A>G p.Y550C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100549462; called by muse, mutect2, varscan2
- AGO4 | c.305G>T p.R102M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV100943105; called by muse, mutect2, varscan2
- AHCY | c.401A>G p.D134G | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99464491; called by muse, mutect2, varscan2
- AHI1 | c.3364C>T p.R1122* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as rs1487081231, COSV55630779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP1 | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.54); PolyPhen benign (0.187); catalogued as rs367715367, COSV100028271; called by muse, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AL049569.3 | c.250C>G p.P84A | Missense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100454489; called by muse, mutect2, varscan2
- AL358113.1 | c.3284G>A p.S1095N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs374359318; ClinVar: uncertain significance; called by muse, varscan2
- ALDOB | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV100878934; called by muse, mutect2, varscan2
- ALG2 | c.1066A>G p.S356G | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768268614, COSV99445745; called by muse, mutect2, varscan2
- ALG9 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV101211956; called by muse, mutect2, varscan2
- ALPI | c.185-2A>G p.X62_splice | Splice Site (SNP) | VAF 22/58 reads (38%) | catalogued as rs1225485149, COSV99786201; called by muse, mutect2, varscan2
- AMER3 | c.440C>A p.P147Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58471381; called by muse, mutect2, varscan2
- AMPD2 | c.1580A>G p.Y527C | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99858167; called by muse, mutect2, varscan2
- ANAPC1 | c.4780G>A p.A1594T | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV100595133; called by muse, mutect2, varscan2
- ANAPC5 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV99946528; called by muse, mutect2, varscan2
- ANGPT1 | c.1036A>G p.M346V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV99864439; called by muse, mutect2, varscan2
- ANGPTL2 | c.725T>C p.I242T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.954); catalogued as COSV99402678; called by muse, mutect2, varscan2
- ANK3 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99782648; called by muse, mutect2, varscan2
- ANK3 | c.574C>A p.L192M | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99781789; called by muse, mutect2, varscan2
- ANK3 | c.76del p.R26Gfs*21 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | catalogued as rs1373792937; called by mutect2, pindel, varscan2
- ANKAR | c.1606A>T p.I536F | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV55612696, COSV99854729; called by muse, mutect2, varscan2
- ANKDD1A | c.354C>A p.H118Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.284); catalogued as COSV100132807; called by muse, mutect2, varscan2
- ANKLE2 | c.1790A>G p.Q597R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV100514387; called by muse, mutect2, varscan2
- ANKMY1 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs778075994, COSV99802162; called by muse, mutect2, varscan2
- ANKRD12 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs780779667, COSV50836171; called by muse, mutect2, varscan2
- ANKRD12 | c.4577del p.N1526Mfs*10 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs768306357; called by mutect2, varscan2
- ANKRD26 | c.4729A>G p.N1577D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as COSV101063444; called by muse, mutect2, varscan2
- ANKRD26 | c.1802_1803del p.K601Rfs*4 | Frame Shift Del (DEL) | VAF 31/93 reads (33%) | catalogued as rs781558318; called by mutect2, pindel, varscan2
- ANO10 | c.1139C>G p.A380G | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99429125; called by muse, mutect2, varscan2
- AOX1 | c.2186A>G p.D729G | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV101022252; called by muse, mutect2, varscan2
- AP1G2 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433925943, COSV99846355, COSV99846389; called by muse, mutect2, varscan2
- AP1G2 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs371013529; called by muse, mutect2, varscan2
- AP1M2 | c.512T>A p.V171D | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99141099; called by muse, mutect2, varscan2
- APAF1 | c.1018T>C p.Y340H (on ENST00000551964 / NM_181861.2; = p.Y329H on NM_001160.3) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1308504401, COSV100244460; called by muse, mutect2, varscan2
- APC | c.3191A>T p.E1064V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.543); catalogued as COSV99970501; called by muse, mutect2, varscan2
- APEH | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs765493835, COSV99609952; called by muse, mutect2, varscan2
- APEH | c.1527del p.X509_splice | Splice Site (DEL) | VAF 21/65 reads (32%) | catalogued as rs1255876232; called by mutect2, pindel, varscan2
- APOB | c.389A>G p.E130G | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759513027, COSV99268387; called by muse, mutect2, varscan2
- AQP3 | c.710+1G>A p.X237_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as rs1347380973, CS024004, COSV99955714; called by muse, mutect2, varscan2
- AQR | c.1699G>A p.V567I | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as rs377699708; called by muse, mutect2, varscan2
- ARHGAP17 | c.2416C>T p.R806W (on ENST00000289968 / NM_001006634.3; = p.R728W on NM_018054.6) | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs1385488478, COSV51510221; called by muse, mutect2
- ARHGAP17 | c.1490+2T>C p.X497_splice | Splice Site (SNP) | VAF 24/62 reads (39%) | catalogued as COSV99254123; called by muse, mutect2, varscan2
- ARHGAP21 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 91/261 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100256724; called by muse, mutect2, varscan2
- ARHGAP36 | c.959T>C p.L320S | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99358271; called by muse, mutect2, varscan2
- ARHGAP39 | c.3251A>G p.*1084Wext*168 (on ENST00000276826 / NM_001308208.2; = p.*1115Wext*168 on NM_025251.2) | Nonstop Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99432336; called by muse, mutect2, varscan2
- ARHGEF12 | c.2764C>T p.R922C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63102620, COSV63107720; called by muse, mutect2, varscan2
- ARHGEF15 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100730189; called by muse, mutect2, varscan2
- ARHGEF17 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs369681028; called by muse, mutect2, varscan2
- ARID4B | c.2900A>G p.E967G | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99936422; called by muse, mutect2, varscan2
- ARMC8 | c.95A>G p.D32G (on ENST00000469044 / NM_001363941.2; = p.D18G on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100627895; called by muse, mutect2, varscan2
- ART5 | c.679del p.H227Mfs*18 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs748137393; called by mutect2, pindel, varscan2
- ASF1B | c.349T>C p.Y117H | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99654419; called by muse, mutect2, varscan2
- ASPA | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.055); catalogued as COSV99559337; called by muse, mutect2, varscan2
- ASXL1 | c.960G>C p.W320C | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100041400; called by muse, mutect2, varscan2
- ASXL3 | c.5971T>C p.S1991P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV99326808; called by muse, mutect2, varscan2
- ATAD2B | c.3477del p.D1160Mfs*20 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | catalogued as rs1558490574; called by mutect2, pindel, varscan2
- ATF6B | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs200008015, COSV64352495; called by muse, mutect2, varscan2
- ATG16L2 | c.1145G>C p.S382T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as COSV100352345; called by muse, mutect2, varscan2
- ATG3 | c.114+2T>C p.X38_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99344428; called by muse, mutect2, varscan2
- ATG4B | c.960G>T p.G320= | Splice Region (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100728808; called by muse, varscan2
- ATG9A | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs200810317, COSV100772695; called by muse, mutect2, varscan2
- ATM | c.2057T>C p.L686P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99592170; called by muse, mutect2, varscan2
- ATP10D | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV99906235; called by muse, mutect2, varscan2
- ATP10D | c.1480G>C p.A494P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.317); catalogued as COSV99906236; called by muse, mutect2, varscan2
- ATP11A | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV99370088; called by muse, mutect2, varscan2
- ATP13A1 | c.1501G>A p.V501I | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs780625699, COSV99366642; called by muse, mutect2, varscan2
- ATP13A1 | c.673A>G p.N225D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99366646; called by muse, mutect2, varscan2
- ATP1A3 | c.779T>C p.V260A (on ENST00000545399 / NM_001256214.2; = p.V247A on NM_152296.5) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV100132566; called by muse, mutect2, varscan2
- ATP8A2 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV54950818; called by muse, mutect2, varscan2
- ATXN2 | c.1634T>C p.V545A (on ENST00000550104; = p.V385A on NM_002973.4) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.251); catalogued as rs774083612, COSV101112911; called by muse, mutect2, varscan2
- AUH | c.870A>T p.K290N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100342855; called by muse, mutect2, varscan2
- B3GALT4 | c.499A>G p.M167V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101005724; called by muse, mutect2, varscan2
- BABAM1 | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.731); catalogued as COSV100845788; called by muse, mutect2, varscan2
- BACH2 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.163); catalogued as rs144153232; called by muse, mutect2, varscan2
- BANP | c.1556A>G p.Q519R (on ENST00000286122; = p.Q469R on NM_017869.4) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV99622452; called by muse, mutect2, varscan2
- BAZ2A | c.2503C>A p.L835M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV99467836; called by muse, varscan2
- BBX | c.2675C>T p.A892V (on ENST00000325805 / NM_001142568.3; = p.A862V on NM_020235.7) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV57881199; called by muse, mutect2, varscan2
- BCKDK | c.1187T>C p.V396A | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV99570909; called by muse, mutect2, varscan2
- BCL2L1 | c.691A>G p.S231G (on ENST00000307677 / NM_001317919.2; = p.S168G on NM_001191.4) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV100304848; called by muse, mutect2, varscan2
- BCO2 | c.1099T>C p.C367R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.908); catalogued as COSV100730508; called by muse, varscan2
- BEGAIN | c.400A>G p.S134G | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100767030; called by muse, mutect2, varscan2
- BFAR | c.1247A>G p.Q416R | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.777); catalogued as COSV55494774; called by muse, mutect2, varscan2
- BGN | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100525294; called by muse, mutect2, varscan2
- BLNK | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199013443, COSV56408891; called by muse, mutect2, varscan2
- BMP2 | c.953del p.P318Rfs*20 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | catalogued as COSV66577125; called by mutect2, pindel, varscan2
- BMP2 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289444520, COSV66578616; called by muse, mutect2
- BMPR1A | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as COSV100776701; called by muse, mutect2, varscan2
- BMX | c.1649T>C p.V550A | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59592259; called by muse, mutect2, varscan2
- BNC2 | c.2957A>G p.E986G | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV101037118; called by muse, mutect2, varscan2
- BOLL | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99987463; called by muse, mutect2, varscan2
- BPNT1 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV100435865; called by muse, mutect2, varscan2
- BRCA2 | c.4447A>C p.T1483P | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); catalogued as COSV101204675; called by muse, mutect2, varscan2
- BRD3 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs1222202262, COSV100325587; called by muse, mutect2, varscan2
- BRD4 | c.3913G>A p.A1305T | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV99651502; called by muse, mutect2, varscan2
- BROX | c.815G>T p.R272M | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100572366; called by muse, mutect2, varscan2
- BTBD11 | c.1909A>G p.T637A (on ENST00000280758 / NM_001018072.2; = p.T174A on NM_001017523.2) | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.621); catalogued as COSV99777093; called by muse, mutect2, varscan2
- BTN3A2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV100709757; called by muse, mutect2, varscan2
- C1QTNF9B | c.604del p.S202Vfs*10 | Frame Shift Del (DEL) | VAF 36/125 reads (29%) | catalogued as rs764936581; called by mutect2, pindel, varscan2
- C1S | c.842del p.K281Rfs*39 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs781818365; called by mutect2, pindel, varscan2
- C2orf78 | c.1070del p.N357Mfs*17 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs1242308663; called by mutect2, pindel, varscan2
- C2orf78 | c.2407A>G p.T803A | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV101281035; called by muse, mutect2, varscan2
- C3 | c.2441-1G>T p.X814_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV55571481, COSV99837321; called by muse, mutect2, varscan2
- C4orf45 | c.305A>C p.E102A | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV101465198; called by muse, mutect2, varscan2
- C9 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as rs148994168; called by muse, mutect2, varscan2
- CA1 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV99810370; called by muse, mutect2, varscan2
- CACNA1E | c.3766T>C p.S1256P | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100705571; called by muse, mutect2, varscan2
- CACNA2D3 | c.638A>G p.Y213C | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99877540; called by muse, mutect2, varscan2
- CADPS | c.3478-2A>G p.X1160_splice | Splice Site (SNP) | VAF 39/87 reads (45%) | catalogued as COSV99341225; called by muse, mutect2, varscan2
- CALCOCO1 | c.1496A>G p.Y499C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1235335693, COSV100017510; called by muse, mutect2, varscan2
- CALD1 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV100724611; called by muse, mutect2
- CAPN15 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99562852; called by muse, mutect2, varscan2
- CAPRIN2 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99195732; called by muse, mutect2, varscan2
- CARNMT1 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100961814; called by muse, mutect2, varscan2
- CASP10 | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99629367; called by muse, mutect2, varscan2
- CATSPER1 | c.1715T>C p.V572A | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100376285; called by muse, mutect2, varscan2
- CAV2 | c.197T>C p.F66S | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV99760873; called by muse, mutect2, varscan2
- CCDC102B | c.1471A>G p.R491G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs759297157, COSV100105041; called by muse, varscan2
- CCDC120 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 31/93 reads (33%) | catalogued as rs1263418293, COSV100900721; called by muse, mutect2, varscan2
- CCDC148 | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99321575; called by muse, mutect2, varscan2
- CCDC34 | c.209T>A p.L70H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100156713; called by muse, mutect2, varscan2
- CCDC66 | c.792del p.A265Pfs*7 (on ENST00000394672 / NM_001353147.1; = p.A231Pfs*7 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs770432647; called by mutect2, pindel, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC80 | c.1599del p.A534Qfs*21 | Frame Shift Del (DEL) | VAF 42/136 reads (31%) | catalogued as rs1414623331; called by mutect2, pindel, varscan2
- CCDC88A | c.3008del p.N1003Ifs*40 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs763821011, COSV55065347; called by mutect2, varscan2
- CCDC88B | c.2617-2A>G p.X873_splice | Splice Site (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100105994; called by muse, mutect2, varscan2
- CCDC93 | c.1826T>A p.V609E | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100099560; called by muse, mutect2, varscan2
- CCN5 | c.730A>G p.S244G | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99509500; called by muse, mutect2, varscan2
- CCNA1 | c.25A>G p.M9V | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs746262330, COSV55223557; called by muse, mutect2, varscan2
- CCR3 | c.701dup p.Y235Vfs*38 | Frame Shift Ins (INS) | VAF 18/45 reads (40%) | catalogued as rs761073142; called by mutect2, varscan2
- CD109 | c.1115T>C p.V372A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV99754754; called by muse, mutect2
- CD209 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as rs142573150; called by muse, mutect2, varscan2
- CD300C | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.243); catalogued as COSV100423357; called by muse, mutect2, varscan2
- CD300LB | c.112T>C p.Y38H | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100075607; called by muse, mutect2, varscan2
- CD320 | c.181T>C p.C61R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100035916; called by muse, mutect2, varscan2
- CD58 | c.307T>C p.Y103H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101044008; called by muse, mutect2, varscan2
- CDC25A | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs1224575878, COSV56769929; called by muse, mutect2, varscan2
- CDCA2 | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV57947930; called by muse, mutect2
- CDH26 | c.163A>G p.R55G | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99723072; called by muse, mutect2, varscan2
- CDH9 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs763497540, COSV50254621, COSV50464003; called by muse, mutect2, varscan2
- CDHR2 | c.2023C>A p.L675I | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99992235; called by muse, mutect2, varscan2
- CDK5R2 | c.760T>C p.S254P | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100225996; called by muse, mutect2, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | catalogued as rs753353408; called by mutect2, varscan2
- CDRT4 | c.359A>G p.H120R | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1023351800, COSV100381616; called by muse, mutect2
- CDX1 | c.736A>G p.S246G | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99199347; called by muse, mutect2, varscan2
- CEP104 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1237002210, COSV65519743; called by muse, mutect2, varscan2
- CEP162 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100003480; called by muse, mutect2, varscan2
- CEP164 | c.3623G>A p.G1208D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99634512; called by muse, mutect2, varscan2
- CEP57L1 | c.1345A>G p.M449V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100425987; called by muse, mutect2, varscan2
- CEP85L | c.1653del p.K551Nfs*16 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as COSV63821513; called by mutect2, varscan2
- CEP89 | c.2233G>A p.V745M | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.026); catalogued as rs745424367, COSV99994065; called by muse, mutect2, varscan2
- CERS2 | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99645945; called by muse, mutect2
- CETP | c.1253G>A p.S418N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99570362; called by muse, mutect2
- CFAP43 | c.4886A>G p.Q1629R | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100312445; called by muse, mutect2, varscan2
- CFAP43 | c.2348A>G p.K783R | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.076); catalogued as COSV99531054; called by muse, mutect2, varscan2
- CFAP57 | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100994116; called by muse, mutect2, varscan2
- CFD | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99516358; called by muse, mutect2, varscan2
- CFH | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as COSV100661673; called by muse, mutect2, varscan2
- CFTR | c.4262T>A p.V1421E | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99140172; called by muse, mutect2, varscan2
- CHMP2B | c.25A>T p.T9S | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99773709; called by muse, mutect2, varscan2
- CHMP6 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100289557; called by muse, mutect2, varscan2
- CHPF | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs779980287, COSV99705350; called by muse, mutect2, varscan2
- CHST5 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); catalogued as rs1321074569, COSV100292141; called by muse, mutect2, varscan2
- CIAO1 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV99720559; called by muse, mutect2, varscan2
- CIBAR1 | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as rs766031533, COSV100844741; called by muse, mutect2, varscan2
- CIBAR1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV100844743; called by muse, varscan2
- CLCA1 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV99322905; called by muse, mutect2, varscan2
- CLCC1 | c.1279_1280dup p.D427Efs*5 (on ENST00000356970 / NM_001377464.1; = p.D377Efs*5 on NM_015127.5) | Frame Shift Ins (INS) | VAF 22/77 reads (29%) | catalogued as rs750385149; called by mutect2, varscan2
- CLCN7 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs758175539, COSV99247681; called by muse, mutect2, varscan2
- CLDN12 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99842258; called by muse, mutect2, varscan2
- CLEC17A | c.385T>C p.C129R | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs747589482, COSV100355594; called by muse, mutect2, varscan2
- CLGN | c.1622del p.K541Sfs*27 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | catalogued as rs1364341002; called by mutect2, pindel, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs369752219; called by mutect2, varscan2
- CLP1 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as rs754578147, COSV57055165; called by muse, mutect2, varscan2
- CLUH | c.3523A>G p.I1175V (on ENST00000435359; = p.I1214V on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.679); catalogued as COSV101425909; called by muse, mutect2, varscan2
- CLUH | c.1448C>T p.T483M (on ENST00000435359; = p.T521M on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs950000630, COSV70927639; called by muse, mutect2, varscan2
- CNKSR1 | c.1535del p.P512Hfs*58 (on ENST00000374253 / NM_001297647.2; = p.P505Hfs*58 on NM_006314.3) | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | catalogued as rs753922055; called by mutect2, pindel, varscan2
- CNOT1 | c.4469A>G p.Q1490R | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV99801387; called by muse, mutect2, varscan2
- CNTN1 | c.568T>C p.S190P | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100751942; called by muse, mutect2, varscan2
- CNTN1 | c.1208A>G p.N403S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0.401); catalogued as COSV100751943; called by muse, mutect2, varscan2
- CNTN5 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs752579089, COSV99681766; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP1 | c.1841A>G p.Y614C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV99227094; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | catalogued as rs748995811; called by mutect2, varscan2
- COL1A1 | c.2462G>A p.G821D | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99868244; called by muse, mutect2, varscan2
- COL20A1 | c.2978A>G p.E993G | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs766590086, COSV100491570; called by muse, varscan2
- COL22A1 | c.4507G>T p.G1503W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100277260; called by muse, mutect2, varscan2
- COL22A1 | c.1901A>G p.K634R | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV100280974; called by muse, mutect2
- COL6A1 | c.1918A>G p.K640E | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.626); catalogued as COSV100720482; called by muse, mutect2, varscan2
- COPB2 | c.761G>C p.R254P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100300910; called by muse, varscan2
- COQ8A | c.853+2T>C p.X285_splice | Splice Site (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100825833; called by muse, mutect2, varscan2
- CORO2B | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs758897752, COSV55957334; called by muse, mutect2, varscan2
- COX10 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV99887163; called by muse, mutect2, varscan2
- CPN2 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.09); catalogued as COSV100103303; called by muse, mutect2, varscan2
- CRACD | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.483); catalogued as COSV99950079; called by muse, mutect2
- CRIPT | c.51T>A p.D17E | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV99482827; called by muse, mutect2, varscan2
- CRTAM | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1034850451, COSV99912330; called by muse, mutect2, varscan2
- CRY2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101314589; called by muse, mutect2, varscan2
- CRYBA4 | c.170T>C p.F57S | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100697872; called by muse, mutect2, varscan2
- CSDE1 | c.2342A>G p.N781S (on ENST00000358528 / NM_001007553.3; = p.N750S on NM_007158.6) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV99796107; called by muse, mutect2, varscan2
- CSDE1 | c.517G>A p.A173T (on ENST00000358528 / NM_001007553.3; = p.A142T on NM_007158.6) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99796110; called by muse, mutect2
- CSMD1 | c.3694G>T p.D1232Y (on ENST00000520002; = p.D1231Y on NM_033225.6) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1446391271, COSV100154265; called by muse, mutect2, varscan2
- CSMD2 | c.6658G>A p.V2220I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs376795247; called by muse, mutect2, varscan2
- CST6 | c.392T>G p.L131R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100376284; called by muse, mutect2, varscan2
- CTCF | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99866681; called by muse, mutect2, varscan2
- CTNNBL1 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs762613570, COSV63743518; called by muse, mutect2
- CTPS1 | c.720+2T>C p.X240_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV101009434; called by muse, mutect2
- CTRL | c.490A>G p.S164G | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99345038; called by muse, mutect2, varscan2
- CTTNBP2 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99354948; called by muse, mutect2, varscan2
- CTU2 | c.246dup p.P83Afs*12 | Frame Shift Ins (INS) | VAF 46/157 reads (29%) | catalogued as rs761639757; called by mutect2, pindel, varscan2
- CUBN | c.2953T>C p.C985R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100913639; called by muse, mutect2, varscan2
- CUL4B | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs760207253, COSV100341242; called by muse, mutect2, varscan2
- CUZD1 | c.1189A>G p.M397V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100159010; called by muse, mutect2, varscan2
- CWC27 | c.747A>G p.E249= | Splice Region (SNP) | VAF 26/88 reads (30%) | catalogued as COSV101126618; called by muse, mutect2, varscan2
- CYP2R1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100584868, COSV100585012; called by muse, mutect2, varscan2
- CYP2U1 | c.901dup p.I301Nfs*11 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs1288449186; called by mutect2, varscan2
- CYTIP | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV99938949; called by muse, mutect2, varscan2
- D2HGDH | c.560T>C p.I187T | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV100344983; called by muse, mutect2, varscan2
- DAAM2 | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.766); catalogued as COSV99227266; called by muse, mutect2, varscan2
- DAAM2 | c.2822C>T p.A941V (on ENST00000274867 / NM_001201427.2; = p.A940V on NM_015345.3) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.338); catalogued as COSV51305909, COSV99227269; called by muse, mutect2
- DAD1 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99164730; called by muse, varscan2
- DAPK1 | c.1510G>A p.V504M | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs372895478; called by muse, mutect2, varscan2
- DCC | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.452); catalogued as COSV100503339; called by muse, mutect2, varscan2
- DCHS1 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.312); catalogued as COSV100202651; called by muse, mutect2, varscan2
- DCTN2 | c.526C>T p.R176C (on ENST00000548249 / NM_001261413.2; = p.R181C on NM_006400.4) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1315316427, COSV63072755, COSV63073084, COSV63074718; called by muse, mutect2, varscan2
- DCUN1D1 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99490090; called by muse, mutect2, varscan2
- DDB1 | c.1871G>A p.S624N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV100074878; called by muse, mutect2, varscan2
- DDX1 | c.954A>G p.L318= | Splice Region (SNP) | VAF 28/57 reads (49%) | catalogued as COSV99247034; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX31 | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.682); catalogued as COSV100140347; called by muse, mutect2, varscan2
- DDX47 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100774664, COSV61911420; called by muse, mutect2, varscan2
- DENND1A | c.1577A>G p.Q526R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1223067691, COSV101011350; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs553532837; called by mutect2, varscan2
- DENND2A | c.143A>G p.D48G | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV99327065; called by muse, mutect2, varscan2
- DENND2B | c.400del p.A135Pfs*18 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as COSV58202741; called by mutect2, pindel, varscan2
- DENND4B | c.3794C>T p.A1265V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.815); catalogued as COSV100768922; called by muse, mutect2, varscan2
- DERL3 | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV99320374; called by muse, mutect2
- DERL3 | c.59A>G p.Y20C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV99320375; called by muse, mutect2
- DGCR2 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs757473727, COSV99594058; called by muse, mutect2, varscan2
- DHRS7C | c.739A>G p.R247G (on ENST00000330255 / NM_001220493.2; = p.R246G on NM_001105571.3) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV100364931; called by muse, mutect2
- DICER1 | c.1584A>G p.I528M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100602595; called by muse, varscan2
- DIP2B | c.2632A>G p.M878V | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as COSV99999511; called by muse, mutect2, varscan2
- DIRAS3 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1215942052, COSV63971123; called by muse, mutect2, varscan2
- DISP2 | c.3926T>C p.V1309A | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as COSV99140595; called by muse, mutect2, varscan2
- DLG1 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100016108; called by muse, mutect2, varscan2
- DLG5 | c.3253T>C p.S1085P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.058); catalogued as COSV100967920; called by muse, mutect2, varscan2
- DLX1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV100250166, COSV59395014; called by muse, mutect2, varscan2
- DLX5 | c.604C>G p.P202A | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV99756716; called by muse, mutect2, varscan2
- DLX5 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV99756721; called by muse, mutect2, varscan2
- DNA2 | c.730A>G p.N244D | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs753253766, COSV100622850; called by muse, varscan2
- DNAAF4 | c.979T>C p.Y327H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100336952; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH17 | c.8038C>T p.L2680F | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.822); catalogued as rs1003163858, COSV101103631; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH8 | c.4418del p.N1473Ifs*15 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs778628413, COSV59486260; called by mutect2, varscan2
- DNAI2 | c.1570A>G p.K524E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100210143; called by muse, mutect2, varscan2
- DNAI4 | c.2440G>T p.G814* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100925505; called by muse, mutect2, varscan2
- DNAJB12 | c.940G>A p.V314M (on ENST00000338820; = p.V280M on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.34); PolyPhen probably damaging (1); catalogued as rs755131366, COSV100123870; called by muse, mutect2
- DNMT3B | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs774138031, COSV99140659; called by muse, mutect2, varscan2
- DOCK11 | c.5932A>G p.K1978E | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.696); catalogued as COSV99354856; called by muse, mutect2, varscan2
- DOCK2 | c.288G>T p.W96C | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV99915819; called by muse, mutect2, varscan2
- DOCK3 | c.2228T>C p.L743P | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1385813525, COSV99815444; called by muse, mutect2, varscan2
- DOCK5 | c.5137G>A p.A1713T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV99377485; called by muse, mutect2, varscan2
- DOCK9 | c.4046A>C p.K1349T (on ENST00000376460 / NM_001366676.2; = p.K1350T on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV100241246; called by muse, mutect2, varscan2
- DPH2 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV99356670; called by muse, mutect2
- DPP6 | c.962C>T p.S321F (on ENST00000377770 / NM_001364500.2; = p.S259F on NM_001936.5) | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100128427; called by muse, mutect2, varscan2
- DPP9 | c.2288A>G p.D763G (on ENST00000598800; = p.D792G on NM_139159.5) | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99506558; called by muse, mutect2, varscan2
- DPYSL4 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100634068; called by muse, mutect2, varscan2
- DRC7 | c.2497T>C p.F833L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1229159215, COSV100395928; called by muse, mutect2, varscan2
- DTX2 | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV100184886; called by muse, mutect2
- DUOX2 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs771688123, COSV99973596; called by muse, mutect2
- DUSP10 | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100100818, COSV60459969; called by muse, mutect2, varscan2
- DYNC1H1 | c.10176G>A p.M3392I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV100795471; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs755197346; called by mutect2, varscan2
- DYNC2I1 | c.1550A>G p.D517G | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV101337729; called by muse, mutect2, varscan2
- DYSF | c.2483G>A p.C828Y | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99250696; called by muse, mutect2, varscan2
- DYSF | c.4429T>C p.W1477R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99250698; called by mutect2, varscan2
- ECE1 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV51665340, COSV51669212; called by muse, mutect2, varscan2
- EDEM1 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849437; called by muse, mutect2, varscan2
- EEFSEC | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as COSV99631529; called by muse, mutect2, varscan2
- EFEMP1 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100816977; called by muse, mutect2, varscan2
- EFEMP2 | c.1220G>A p.G407D | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100337415; called by muse, mutect2, varscan2
- EIF2AK4 | c.1390G>T p.V464F | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99775438; called by muse, mutect2, varscan2
- EIF3G | c.466T>C p.S156P | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.699); catalogued as COSV99462984; called by muse, mutect2, varscan2
- EIF4B | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as rs758335712, COSV50408768; called by muse, mutect2, varscan2
- EIF5 | c.404A>G p.H135R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV99385032; called by muse, mutect2, varscan2
- EIF5B | c.3191A>G p.H1064R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV99178919; called by muse, mutect2, varscan2
- ELK3 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99957823; called by muse, mutect2, varscan2
- ELL | c.1372A>G p.K458E | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.097); catalogued as rs1362661207, COSV99443790; called by muse, mutect2, varscan2
- ELOVL3 | c.100T>C p.W34R | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV100892850; called by muse, mutect2, varscan2
- EMSY | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); catalogued as COSV100596104; called by muse, varscan2
- EP400 | c.8624T>C p.V2875A | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100202413; called by muse, mutect2, varscan2
- EPB41L1 | c.2104G>A p.V702I | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.275); catalogued as COSV99152107; called by muse, mutect2, varscan2
- EPB41L2 | c.1922T>C p.I641T | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV100441464; called by muse, mutect2, varscan2
- EPB41L3 | c.3130del p.D1044Mfs*26 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as COSV59471224; called by mutect2, pindel, varscan2
- EPHB3 | c.2371A>G p.T791A | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.371); catalogued as rs772853395, COSV100383314; called by muse, mutect2, varscan2
- EPHX2 | c.548dup p.L183Ffs*3 | Frame Shift Ins (INS) | VAF 40/106 reads (38%) | catalogued as rs1442463502; called by mutect2, varscan2
- EPHX3 | c.1033del p.Q345Rfs*51 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as rs770539760; called by mutect2, pindel, varscan2
- EPN2 | c.1796A>G p.Q599R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV100127768; called by muse, mutect2, varscan2
- EPOR | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.168); catalogued as COSV99710322; called by muse, mutect2, varscan2
- EPS8L1 | c.752T>C p.V251A (on ENST00000201647 / NM_133180.3; = p.V124A on NM_017729.3) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99137211; called by muse, mutect2, varscan2
- ERC1 | c.1246A>G p.T416A | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100706812; called by muse, mutect2, varscan2
- ERCC4 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as rs776880848, COSV100319141; called by muse, varscan2
- ERG | c.1397del p.G466Vfs*46 (on ENST00000398919 / NM_001243428.1; = p.G442Vfs*46 on NM_004449.4) | Frame Shift Del (DEL) | VAF 42/112 reads (38%) | catalogued as COSV55739379; called by mutect2, pindel, varscan2
- ERG28 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as rs1326266174, COSV99709803; called by muse, mutect2, varscan2
- ERICH3 | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100445933; called by muse, mutect2, varscan2
- ESF1 | c.1929A>T p.K643N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV99176553; called by muse, mutect2, varscan2
- ESPL1 | c.3730C>T p.Q1244* | Nonsense Mutation (SNP) | VAF 33/62 reads (53%) | catalogued as COSV99229836; called by muse, mutect2, varscan2
- ETF1 | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV100860299; called by muse, mutect2, varscan2
- ETNK2 | c.536T>C p.M179T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100916682; called by muse, mutect2, varscan2
- ETV7 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100339349; called by muse, mutect2, varscan2
- EVA1C | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100291624; called by muse, mutect2, varscan2
- EVC2 | c.3639G>A p.W1213* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100187038, COSV60399299; called by muse, mutect2, varscan2
- EVI5 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100789694; called by muse, mutect2, varscan2
- EVI5L | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99563584; called by muse, mutect2, varscan2
- EXOC4 | c.1876A>G p.I626V | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs758777671, COSV99555914; called by muse, mutect2, varscan2
- EXOC6B | c.1027T>C p.Y343H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99726672; called by muse, mutect2
- EXOSC9 | c.959A>G p.E320G | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99697185; called by muse, mutect2, varscan2
- EXTL1 | c.830G>A p.G277D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100959136; called by muse, mutect2
- F7 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 38/93 reads (41%) | catalogued as COSV100661115; called by muse, mutect2, varscan2
- F9 | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs768416668, CD125318, COSV99496928; called by muse, mutect2, varscan2
- FABP1 | c.371G>A p.S124N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55557816, COSV99860995; called by muse, mutect2
- FADS3 | c.907T>C p.F303L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV99605528; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM118B | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100796936; called by muse, mutect2, varscan2
- FAM120B | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs761235189, COSV53001167; called by muse, mutect2, varscan2
- FAM135B | c.3707A>G p.Y1236C | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99428139; called by muse, mutect2, varscan2
- FAM135B | c.446A>G p.H149R | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99358311; called by muse, mutect2, varscan2
- FAM151A | c.1210A>G p.T404A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100157144; called by muse, mutect2, varscan2
- FAM161A | c.559A>G p.R187G | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100281569; called by muse, mutect2, varscan2
- FAM166C | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99719126; called by muse, mutect2, varscan2
- FAM181B | c.311G>A p.C104Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100235168; called by muse, mutect2
- FAM217A | c.830A>G p.D277G | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV99212815; called by muse, mutect2, varscan2
- FAM53B | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs149967922; called by mutect2, varscan2
- FAM83G | c.823T>C p.W275R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100525558; called by muse, mutect2, varscan2
- FANCI | c.3677C>T p.T1226M (on ENST00000310775 / NM_001376911.1; = p.T1166M on NM_018193.3) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.646); catalogued as rs367665900; called by muse, mutect2, varscan2
- FARP1 | c.1598G>T p.R533M | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV100132244; called by muse, mutect2, varscan2
- FASN | c.4574A>G p.E1525G | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.076); catalogued as COSV100148381; called by muse, mutect2, varscan2
- FAT1 | c.13564G>T p.G4522W | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499665; called by muse, mutect2, varscan2
- FAT2 | c.11156G>A p.R3719Q | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as rs1344751631, COSV55820109; called by muse, mutect2, varscan2
- FAT2 | c.6946T>C p.S2316P | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as COSV99944244; called by muse, mutect2, varscan2
- FAT3 | c.1080G>T p.K360N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV99971546; called by muse, mutect2, varscan2
- FAT4 | c.8758T>C p.F2920L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100630384, COSV58671625; called by muse, mutect2, varscan2
- FAT4 | c.14801A>G p.N4934S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV100630387; called by muse, mutect2, varscan2
- FBN2 | c.6202C>T p.L2068F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.767); catalogued as COSV52504383, COSV99330984; called by muse, mutect2, varscan2
- FBN2 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1364729505, COSV52508292; called by muse, mutect2, varscan2
- FBN3 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99561928; called by muse, mutect2, varscan2
- FBXO15 | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV99503846; called by muse, mutect2, varscan2
- FBXO30 | c.1023A>G p.I341M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99395446; called by muse, varscan2
- FCRL5 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.911); catalogued as COSV100709375; called by muse, varscan2
- FCRL5 | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.517); catalogued as COSV100709376; called by muse, varscan2
- FER1L5 | c.4304A>T p.Y1435F (on ENST00000623019; = p.Y1408F on NM_001293083.2) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as COSV101208920; called by muse, mutect2, varscan2
- FERMT2 | c.455del p.K152Rfs*4 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs766229731; called by mutect2, varscan2
- FGF12 | c.308A>G p.Y103C (on ENST00000454309 / NM_021032.5; = p.Y41C on NM_004113.6) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.743); catalogued as rs1229502475, COSV99279037; called by muse, mutect2, varscan2
- FKBP4 | c.1034C>A p.A345D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99134034; called by muse, mutect2, varscan2
- FKRP | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100586734; called by muse, varscan2
- FLNA | c.1595A>G p.D532G | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.665); catalogued as COSV100775302; called by muse, mutect2, varscan2
- FLT4 | c.3757A>G p.K1253E | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV99989226; called by muse, mutect2
- FNBP4 | c.1268A>G p.E423G | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99772014; called by muse, mutect2, varscan2
- FNDC1 | c.5584T>C p.Y1862H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99797052; called by muse, mutect2
- FOSL2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305140602, COSV53103916, COSV53104289; called by muse, mutect2
- FOXA2 | c.699G>C p.W233C (on ENST00000377115 / NM_153675.3; = p.W239C on NM_021784.5) | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101008523; called by muse, mutect2, varscan2
- FOXD4L5 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as rs752080978, COSV101073288; called by muse, mutect2, varscan2
- FOXG1 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100487098; called by muse, mutect2, varscan2
- FOXN1 | c.1898G>C p.G633A | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as COSV99881566; called by muse, mutect2, varscan2
- FOXRED2 | c.1523A>G p.K508R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV99341161; called by muse, mutect2, varscan2
- FRY | c.682T>C p.Y228H | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66572944; called by muse, mutect2, varscan2
- FRY | c.7130T>C p.V2377A | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100969990; called by muse, mutect2, varscan2
- FSTL4 | c.2149A>G p.T717A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99533892; called by muse, mutect2, varscan2
- FTL | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.204); catalogued as COSV99509285; called by muse, mutect2, varscan2
- FUBP3 | c.772-2A>G p.X258_splice | Splice Site (SNP) | VAF 25/63 reads (40%) | catalogued as COSV100156343; called by muse, varscan2
- FUT10 | c.740T>C p.L247S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100161800; called by muse, mutect2, varscan2
- FYCO1 | c.2047G>T p.A683S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.515); catalogued as COSV56116442, COSV99946327; called by muse, mutect2, varscan2
- G0S2 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV100884480; called by muse, mutect2, varscan2
- G2E3 | c.2067A>G p.I689M | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV99249934; called by muse, mutect2, varscan2
- GAA | c.858+2T>C p.X286_splice | Splice Site (SNP) | VAF 18/58 reads (31%) | catalogued as CS120516, COSV100163563; called by mutect2, varscan2
- GAA | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs778874712, COSV100163564; called by muse, mutect2, varscan2
- GABRA5 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100164839; called by muse, mutect2, varscan2
- GABRB2 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99196761; called by muse, mutect2, varscan2
- GABRE | c.377G>A p.W126* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100944402; called by muse, mutect2, varscan2
- GAD1 | c.89A>G p.D30G | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100713945; called by muse, mutect2, varscan2
- GALNT16 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776397071, COSV100546217; called by muse, mutect2, varscan2
- GAMT | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99283047; called by muse, mutect2, varscan2
- GAPVD1 | c.4330T>C p.Y1444H (on ENST00000394104; = p.Y1453H on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52921500; called by muse, mutect2, varscan2
- GAS2 | c.836G>A p.G279D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.391); catalogued as COSV99535786; called by muse, mutect2, varscan2
- GAS6 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.845); catalogued as COSV100582313; called by muse, mutect2
- GBE1 | c.2011del p.S671Lfs*36 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | catalogued as rs780374709; called by mutect2, pindel, varscan2
- GBX1 | c.1042T>C p.F348L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs1045636166, COSV99881151; called by muse, mutect2, varscan2
- GCN1 | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.308); catalogued as rs988502218, COSV56113522; called by muse, mutect2, varscan2
- GGH | c.606+2T>C p.X202_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99479052; called by muse, mutect2, varscan2
- GGT7 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.131); catalogued as rs765192846, COSV100322237; called by muse, mutect2, varscan2
- GID4 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99254330; called by muse, mutect2, varscan2
- GK | c.800C>T p.S267F (on ENST00000427190 / NM_001205019.2; = p.S261F on NM_000167.6) | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100971011; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 20/34 reads (59%) | catalogued as rs749150409; called by mutect2, varscan2
- GOSR1 | c.216T>G p.I72M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99853829; called by muse, mutect2, varscan2
- GOT1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100981797, COSV100981832; called by muse, mutect2, varscan2
- GOT1 | c.550T>C p.F184L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100981839; called by muse, mutect2, varscan2
- GPR101 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as COSV99981697; called by muse, mutect2, varscan2
- GPR174 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.105); catalogued as rs1489127095, COSV52133424; called by muse, mutect2, varscan2
- GPR34 | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.889); catalogued as COSV100587825; called by muse, mutect2, varscan2
- GPR35 | c.695C>A p.P232H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100166710; called by muse, mutect2, varscan2
- GPR75 | c.1126T>A p.Y376N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100766498; called by muse, mutect2, varscan2
- GPRIN1 | c.778A>G p.R260G | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99992236; called by muse, mutect2, varscan2
- GPT | c.860A>G p.H287R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV99477875; called by muse, mutect2, varscan2
- GPT | c.1419dup p.E475Gfs*72 | Frame Shift Ins (INS) | VAF 30/97 reads (31%) | catalogued as rs776744432; called by mutect2, pindel, varscan2
- GRID2 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99947427; called by muse, mutect2, varscan2
- GRIN3A | c.1555A>G p.T519A | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV100701881; called by muse, mutect2, varscan2
- GRIP2 | c.2648C>A p.S883Y (on ENST00000619221; = p.S786Y on NM_001080423.4) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99817737; called by muse, mutect2, varscan2
- GRTP1 | c.262A>G p.M88V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV58151584; called by muse, mutect2, varscan2
- GSG1 | c.659T>C p.M220T (on ENST00000651961 / NM_001080555.4; = p.H225= on NM_031289.5) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as COSV99546008; called by muse, mutect2, varscan2
- GSTCD | c.326T>C p.L109S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100853883; called by muse, mutect2, varscan2
- GSTO1 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.896); catalogued as COSV100086848; called by muse, mutect2, varscan2
- GTF2H3 | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as rs962979228, COSV99967682; called by muse, mutect2, varscan2
- GUCY1B1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs776905298, COSV52375040; called by muse, mutect2, varscan2
- GUCY2F | c.2938C>T p.R980* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as rs767389454, COSV54306635, COSV99485743; called by muse, mutect2, varscan2
- GUSB | c.1705T>C p.Y569H | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.773); catalogued as COSV100512786; called by muse, mutect2, varscan2
- GYS1 | c.2093C>T p.S698F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV99621245; called by muse, mutect2, varscan2
- GYS1 | c.1867T>C p.Y623H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.925); catalogued as COSV99621249; called by muse, mutect2, varscan2
- H1-1 | c.513dup p.P172Tfs*11 | Frame Shift Ins (INS) | VAF 30/102 reads (29%) | catalogued as rs749012967; called by mutect2, varscan2
- H2BU1 | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); catalogued as COSV100797325; called by muse, mutect2, varscan2
- H6PD | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs146173767; called by muse, varscan2
- HADHB | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.048); catalogued as rs1343638857, COSV100502184; called by muse, mutect2, varscan2
- HAS3 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV99544785; called by muse, mutect2, varscan2
- HAUS5 | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99178839; called by muse, mutect2, varscan2
- HDAC3 | c.280T>C p.C94R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99781555; called by muse, mutect2, varscan2
- HDGFL3 | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV100220950; called by muse, mutect2, varscan2
- HDLBP | c.3289-3del | Splice Region (DEL) | VAF 23/51 reads (45%) | catalogued as rs778255938; called by mutect2, pindel, varscan2
- HECTD4 | c.10370A>G p.K3457R | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1388800720, COSV101108401; called by muse, mutect2
- HERC2 | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99877122; called by muse, mutect2, varscan2
- HERPUD2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1407087419, COSV100257782; called by muse, mutect2
- HGF | c.1718G>A p.G573D | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99738686; called by muse, mutect2, varscan2
- HGF | c.1379C>A p.P460H | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55947960, COSV99738689; called by muse, mutect2, varscan2
- HIC2 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101335624; called by muse, mutect2, varscan2
- HIC2 | c.1513T>G p.F505V | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV101335643; called by muse, mutect2, varscan2
- HIC2 | c.1718A>G p.Q573R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV101335644; called by muse, mutect2, varscan2
- HIPK1 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as rs192499620, COSV65784410; called by muse, mutect2, varscan2
- HLA-DQA2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as rs1226765994, COSV100890814; called by muse, varscan2
- HMGCS1 | c.1543A>G p.I515V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV100285086; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs761272507; called by mutect2, varscan2*
- HOXA1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV99761434; called by muse, mutect2, varscan2
- HOXA4 | c.8T>C p.M3T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1033347600, COSV100415726; called by muse, mutect2, varscan2
- HPR | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.243); catalogued as COSV99931051; called by muse, mutect2, varscan2
- HS3ST6 | c.971A>G p.Y324C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559262531, COSV99562893; called by muse, mutect2
- HSD17B4 | c.264_266del p.R90del (on ENST00000414835 / NM_001199291.3; = p.R65del on NM_000414.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs770940142; called by pindel, varscan2
- HSP90AB1 | c.910T>C p.F304L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100807229; called by muse, mutect2, varscan2
- HSPA2 | c.1733A>G p.Q578R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as COSV99905173; called by muse, mutect2, varscan2
- HSPG2 | c.9667G>A p.V3223M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs772038023, COSV101013566; called by muse, mutect2, varscan2
- HTR1B | c.913A>G p.M305V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV100885504; called by muse, mutect2, varscan2
- HTR5A | c.880T>C p.F294L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1267821158, COSV99840026; called by muse, mutect2, varscan2
- HUWE1 | c.440A>G p.Y147C | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV99473964; called by muse, mutect2, varscan2
- HYDIN | c.14077C>T p.P4693S | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204780096, COSV101125233; called by muse, mutect2, varscan2
- IBA57 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs145655747; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 50/80 reads (63%) | catalogued as rs747841314; called by mutect2, varscan2
- ICE2 | c.2239A>G p.S747G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV99831879; called by muse, mutect2, varscan2
- IFI44 | c.170A>C p.E57A | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.157); catalogued as COSV100877441; called by muse, mutect2, varscan2
- IFIH1 | c.2897A>G p.Q966R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV99718933; called by muse, mutect2, varscan2
- IFIT1 | c.764G>C p.R255P | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100878658, COSV100878779; called by muse, mutect2, varscan2
- IGBP1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as COSV100643077; called by muse, mutect2, varscan2
- IGFBP4 | c.589T>C p.Y197H | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99511297; called by muse, mutect2, varscan2
- IGKV2D-28 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV101494569; called by muse, mutect2, varscan2
- IGSF1 | c.3955A>G p.N1319D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100812390; called by muse, mutect2, varscan2
- IGSF21 | c.791A>G p.N264S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99246385; called by muse, mutect2, varscan2
- IGSF8 | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV100081851; called by muse, mutect2, varscan2
- IL16 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.895); catalogued as rs755840289, COSV57264527, COSV57269432; called by muse, mutect2, varscan2
- IL1R2 | c.246_248del p.E83del | In Frame Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs1203755411; called by pindel, varscan2
- IL1RAP | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV99300286; called by muse, mutect2, varscan2
- IL21 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99144498; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IMP4 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs775723557, COSV99383872; called by muse, mutect2, varscan2
- INO80E | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV99663360; called by muse, mutect2, varscan2
- INPPL1 | c.3176C>T p.P1059L | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs769801718, COSV99996702; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs760925109; called by mutect2, pindel
- INS-IGF2 | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV99171172, COSV99171175; called by muse, mutect2, varscan2
- IP6K2 | c.86A>G p.H29R | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100152146; called by muse, mutect2, varscan2
- IQCB1 | c.1309A>G p.K437E | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as rs926668992, COSV100182171; called by muse, mutect2
- IRF2 | c.521A>T p.N174I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV101165914; called by muse, mutect2, varscan2
- ISCA2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV99467374; called by muse, mutect2, varscan2
- ISG20L2 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100494121; called by muse, mutect2, varscan2
- ISLR2 | c.1160A>G p.E387G | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV100679806; called by muse, mutect2, varscan2
- ITGA1 | c.2252T>C p.V751A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV99252265; called by muse, mutect2
- ITGA10 | c.241del p.A81Pfs*11 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as rs782249120, COSV65196144, COSV65198308; called by pindel, varscan2
- ITIH2 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs370246983; called by muse, mutect2, varscan2
- ITIH4 | c.2686A>G p.T896A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.077); catalogued as rs768308001, COSV99819949; called by muse, varscan2
- ITPR3 | c.4187T>C p.V1396A | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV100968177; called by muse, mutect2, varscan2
- IVNS1ABP | c.1480A>T p.S494C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100832870; called by muse, varscan2
- IYD | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.763); catalogued as rs777194249, COSV57604315; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | catalogued as COSV100584246; called by muse, mutect2, varscan2
- KALRN | c.4319A>C p.K1440T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99567540; called by muse, mutect2, varscan2
- KAT6A | c.5008C>T p.P1670S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.011); catalogued as COSV99705979; called by muse, mutect2, varscan2
- KATNIP | c.851A>G p.N284S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV99852100; called by muse, mutect2, varscan2
- KBTBD6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 23/69 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as rs562972797, COSV101068896; called by muse, mutect2, varscan2
- KCNA7 | c.932A>G p.E311G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs150070811; called by muse, mutect2, varscan2
- KCNB2 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.999); catalogued as COSV101579025; called by muse, mutect2, varscan2
- KCNC4 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as rs994937743, COSV100873698; called by muse, mutect2, varscan2
- KCND2 | c.13del p.V5Wfs*41 | Frame Shift Del (DEL) | VAF 36/149 reads (24%) | catalogued as COSV58583583, COSV58589056; called by mutect2, pindel, varscan2
- KCNH1 | c.2480dup p.G828Rfs*21 (on ENST00000271751 / NM_172362.3; = p.G801Rfs*21 on NM_002238.4) | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | catalogued as rs1558421105; called by mutect2, pindel, varscan2
- KCNH3 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.137); catalogued as COSV99235868; called by muse, mutect2
- KCNH4 | c.1060T>C p.Y354H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99237977; called by muse, mutect2, varscan2
- KCNJ8 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV99557744; called by muse, mutect2, varscan2
- KCNJ8 | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99557745; called by muse, mutect2
- KCNV2 | c.1135A>G p.M379V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.097); catalogued as rs370412027; called by muse, mutect2, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs754600318; called by mutect2, pindel, varscan2
- KCTD7 | c.643T>C p.W215R (on ENST00000275532; = p.V228A on NM_153033.5) | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as COSV99299319; called by muse, mutect2, varscan2
- KDM3B | c.2765A>G p.Y922C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV100070290; called by muse, mutect2, varscan2
- KDM3B | c.3098T>C p.V1033A | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.12); catalogued as COSV100070291; called by muse, mutect2, varscan2
- KIAA0586 | c.1244T>C p.V415A (on ENST00000619416 / NM_001244190.2; = p.V430A on NM_014749.5) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99709032; called by muse, mutect2, varscan2
- KIAA1210 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.028); catalogued as COSV101274423; called by muse, mutect2, varscan2
- KIF14 | c.3334A>G p.R1112G | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100951100; called by muse, mutect2, varscan2
- KIF21B | c.2419C>T p.Q807* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100145198; called by muse, mutect2
- KIF21B | c.1664A>G p.E555G | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as COSV100145199; called by muse, mutect2, varscan2
- KIF26B | c.3986G>A p.C1329Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs768878657, COSV100833524; called by muse, mutect2, varscan2
- KIF4A | c.2797T>C p.Y933H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as COSV100979659; called by muse, mutect2, varscan2
- KIF5A | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99673640; called by muse, mutect2, varscan2
- KIF5B | c.602G>A p.S201N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100192443; called by muse, mutect2, varscan2
- KIFBP | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752833136, COSV62831808; called by muse, mutect2, varscan2
- KIFC3 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV101109400; called by muse, mutect2, varscan2
- KLF7 | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as rs779150059, COSV100519428; called by muse, mutect2, varscan2
- KLHL22 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100186291; called by muse, mutect2, varscan2
- KLK14 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99336072; called by muse, mutect2, varscan2
- KLK3 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100386128; called by muse, mutect2, varscan2
- KLRD1 | c.104T>C p.F35S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV100282321; called by muse, varscan2
- KLRD1 | c.163+2T>C p.X55_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100282323; called by muse, varscan2
- KMO | c.687+2T>C p.X229_splice | Splice Site (SNP) | VAF 27/76 reads (36%) | catalogued as COSV100844725; called by muse, mutect2, varscan2
- KMT2D | c.6354del p.A2119Lfs*25 | Frame Shift Del (DEL) | VAF 15/32 reads (47%) | catalogued as COSV56474038; called by mutect2, varscan2
- KMT2D | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV99986228; called by muse, mutect2, varscan2
- KMT2D | c.2506del p.Q836Sfs*94 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as COSV56411048; called by mutect2, pindel, varscan2
- KNCN | c.307A>G p.S103G (on ENST00000481882 / NM_001322255.2; = p.S80G on NM_001097611.1) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV99606373; called by muse, mutect2, varscan2
- KNDC1 | c.1576-2A>G p.X526_splice | Splice Site (SNP) | VAF 117/159 reads (74%) | catalogued as COSV100466368; called by muse, mutect2, varscan2
- KPNB1 | c.207T>A p.D69E | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.222); catalogued as COSV99268436; called by muse, mutect2
- KRBA1 | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99753169; called by muse, mutect2, varscan2
- KRT15 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99563312; called by muse, mutect2, varscan2
- KRT33A | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as COSV50365293, COSV99145023; called by muse, mutect2, varscan2
- KRT38 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV99878421; called by muse, mutect2, varscan2
- KRT5 | c.319T>C p.F107L | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99358306; called by muse, mutect2, varscan2
- KRT72 | c.301A>T p.T101S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as COSV99537519; called by muse, mutect2, varscan2
- KRTAP10-5 | c.90del p.C31Afs*7 | Frame Shift Del (DEL) | VAF 45/148 reads (30%) | catalogued as rs782662409; called by mutect2, pindel, varscan2
- LAMA3 | c.4925C>T p.T1642I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as COSV99335928; called by muse, mutect2, varscan2
- LAMA5 | c.7217A>G p.Q2406R | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99442653; called by muse, varscan2
- LAMB4 | c.26del p.L9Cfs*43 | Frame Shift Del (DEL) | VAF 18/41 reads (44%) | catalogued as rs747409331; called by mutect2, pindel, varscan2
- LAMP5 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as COSV99855616; called by muse, mutect2, varscan2
- LAP3 | c.1193T>C p.V398A | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV99884650; called by muse, mutect2, varscan2
- LARS1 | c.2789T>C p.L930P (on ENST00000394434 / NM_020117.11; = p.L903P on NM_016460.3) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99198919; called by muse, mutect2, varscan2
- LATS1 | c.2780A>G p.Y927C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99486780; called by muse, mutect2, varscan2
- LCMT1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376104801; called by muse, mutect2, varscan2
- LDHD | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100097605; called by muse, mutect2, varscan2
- LENG8 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs139748316, COSV58730693; called by muse, mutect2, varscan2
- LENG8 | c.2150T>G p.L717R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100418231; called by muse, mutect2, varscan2
- LGI3 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100102993; called by muse, mutect2, varscan2
- LHFPL5 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1007579426, COSV100799035; called by muse, mutect2, varscan2
- LIG4 | c.2327A>G p.E776G | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as COSV100800087; called by muse, mutect2, varscan2
- LIN7A | c.143A>G p.H48R | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.216); catalogued as COSV54026696, COSV99692769; called by muse, mutect2, varscan2
- LIPA | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99261036; called by muse, mutect2, varscan2
- LIPH | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.381); catalogued as COSV99956362; called by muse, mutect2, varscan2
- LMBRD2 | c.272+2T>C p.X91_splice | Splice Site (SNP) | VAF 22/55 reads (40%) | catalogued as rs1456963845, COSV99683289; called by muse, mutect2, varscan2
- LMF2 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1262063869, COSV99327813; called by muse, mutect2
- LONRF2 | c.1499A>G p.N500S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as COSV101111066; called by muse, mutect2, varscan2
- LRBA | c.7415G>A p.R2472Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.301); catalogued as COSV63949907; called by muse, mutect2, varscan2
- LRP1B | c.10744G>A p.E3582K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV67266617; called by muse, mutect2, varscan2
- LRP2 | c.6133T>C p.C2045R | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99790450; called by muse, mutect2, varscan2
- LRP5 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.901); catalogued as COSV53718264; called by muse, mutect2, varscan2
- LRRC17 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs371158213; called by muse, mutect2, varscan2
- LRRC3 | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV99381852; called by muse, mutect2, varscan2
- LRRC41 | c.1961T>C p.M654T | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100586569; called by muse, mutect2, varscan2
- LRRC55 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); catalogued as COSV101546789; called by muse, mutect2, varscan2
- LRRC6 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.157); catalogued as COSV99138678; called by muse, mutect2, varscan2
- LRRC6 | c.11T>C p.I4T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1339194509, COSV99138686; called by muse, mutect2, varscan2
- LRRC61 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99784785; called by muse, mutect2, varscan2
- LRRC66 | c.1223del p.K408Sfs*42 | Frame Shift Del (DEL) | VAF 27/79 reads (34%) | catalogued as rs752924856; called by mutect2, varscan2
- LTBP4 | c.4224dup p.A1409Rfs*3 (on ENST00000308370 / NM_001042544.1; = p.A1372Rfs*3 on NM_003573.2) | Frame Shift Ins (INS) | VAF 14/68 reads (21%) | catalogued as rs754757253; called by mutect2, varscan2
- LTN1 | c.1553T>C p.L518P | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100798255; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.719); catalogued as rs764850579, COSV65419317; called by muse, mutect2, varscan2
- LYPD5 | c.197A>G p.Y66C (on ENST00000377950 / NM_001031749.3; = p.Y23C on NM_182573.2) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100935318; called by muse, mutect2, varscan2
- LZTS2 | c.7A>G p.I3V | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs1429116855, COSV100932299; called by muse, mutect2, varscan2
- MAB21L2 | c.62A>G p.Q21R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.111); catalogued as COSV100462462; called by muse, mutect2, varscan2
- MACROH2A1 | c.793G>T p.G265C (on ENST00000510038; = p.G264C on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100427770; called by muse, mutect2, varscan2
- MACROH2A1 | c.492A>C p.E164D (on ENST00000510038; = p.E163D on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100427774; called by muse, mutect2, varscan2
- MAEA | c.1062G>A p.M354I (on ENST00000303400 / NM_001017405.3; = p.M313I on NM_005882.5) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV99295733; called by muse, mutect2, varscan2
- MALSU1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as COSV99799981; called by muse, mutect2, varscan2
- MAMDC2 | c.1880T>C p.L627P | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV101015882; called by muse, mutect2, varscan2
- MAMSTR | c.485dup p.H163Tfs*9 (on ENST00000318083 / NM_001130915.2; = p.H60Tfs*9 on NM_182574.2) | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | catalogued as rs752869239; called by mutect2, varscan2
- MAN1B1 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100858165; called by muse, mutect2, varscan2
- MAN1B1 | c.1825C>A p.R609S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100857434; called by muse, mutect2, varscan2
- MAN1C1 | c.1296dup p.L433Afs*67 | Frame Shift Ins (INS) | VAF 8/35 reads (23%) | catalogued as rs759630213; called by mutect2, pindel, varscan2
- MAN2A1 | c.2482A>G p.R828G | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs1382651989, COSV99811984; called by muse, mutect2, varscan2
- MAN2B2 | c.1591A>G p.T531A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.199); catalogued as COSV99578158; called by muse, mutect2, varscan2
- MAN2C1 | c.2251C>T p.P751S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV51239163; called by muse, mutect2, varscan2
- MAP1B | c.1243dup p.M415Nfs*5 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as rs1460938294; called by mutect2, pindel, varscan2
- MAP3K11 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV100482769; called by muse, mutect2, varscan2
- MAP3K13 | c.1925A>G p.Q642R | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99408067; called by muse, mutect2, varscan2
- MAP4K3 | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1293467315, COSV99811187; called by muse, mutect2, varscan2
- MAPK12 | c.691+2T>C p.X231_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV53131994, COSV99299721; called by muse, mutect2
- MAPK8 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.98); catalogued as rs1422869920, COSV100827565; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 13/42 reads (31%) | catalogued as rs777328830; called by mutect2, varscan2
- MARCHF4 | c.327del p.L110Cfs*49 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as COSV56104526; called by mutect2, pindel, varscan2
- MAST2 | c.1572-1G>T p.X524_splice | Splice Site (SNP) | VAF 39/100 reads (39%) | catalogued as COSV100788843; called by muse, mutect2, varscan2
- MAT2B | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99796975; called by muse, mutect2, varscan2
- MATN2 | c.1976T>A p.V659E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99647229; called by muse, mutect2, varscan2
- MBD4 | c.1390A>G p.I464V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs527715494, COSV99999031; called by muse, mutect2, varscan2
- MCM3AP | c.2087T>C p.V696A | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs922605672, COSV99387579; called by muse, mutect2, varscan2
- MCM4 | c.717G>T p.M239I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100031882; called by muse, mutect2, varscan2
- MECOM | c.1577A>G p.D526G (on ENST00000468789 / NM_001105078.4; = p.D714G on NM_004991.4) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.793); catalogued as COSV99245625; called by muse, mutect2, varscan2
- MED13 | c.6398T>C p.V2133A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101181441; called by muse, mutect2, varscan2
- MED25 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.046); catalogued as rs1226357178, COSV100458057; called by muse, mutect2
- MEGF10 | c.496G>C p.A166P | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99175771; called by muse, mutect2, varscan2
- MEGF6 | c.4318del p.A1440Hfs*78 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | catalogued as rs759225724, COSV53895347; called by mutect2, pindel, varscan2
- MFHAS1 | c.1871T>C p.V624A | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99359600, COSV99359982; called by muse, mutect2, varscan2
- MFN2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1011639786, COSV52420534; called by muse, mutect2, varscan2
- MGAM | c.3716T>C p.V1239A | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV101527778; called by muse, mutect2, varscan2
- MGAT1 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | PolyPhen benign (0.003); catalogued as rs762037486, COSV100286853; called by muse, mutect2, varscan2
- MGAT5B | c.293A>G p.H98R | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100049024; called by muse, mutect2, varscan2
- MGLL | c.266T>C p.V89A (on ENST00000398104 / NM_001003794.2; = p.V99A on NM_007283.6) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.085); catalogued as COSV99412104; called by muse, mutect2, varscan2
- MID2 | c.803G>A p.C268Y | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99465720; called by muse, mutect2, varscan2
- MINK1 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100767304; called by mutect2, varscan2
- MISP | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs761707209, COSV53121193; called by muse, mutect2, varscan2
- MITD1 | c.713T>C p.V238A | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99175590; called by muse, mutect2, varscan2
- MIXL1 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as COSV100830843; called by muse, mutect2, varscan2
- MKI67 | c.3638C>G p.T1213S | Missense Mutation (SNP) | VAF 89/113 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100897032; called by muse, mutect2, varscan2
- MLLT1 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV99398279; called by muse, mutect2, varscan2
- MMP16 | c.402C>T p.Y134= | Splice Region (SNP) | VAF 25/69 reads (36%) | catalogued as COSV54159956, COSV99690627; called by muse, mutect2, varscan2
- MMP3 | c.820dup p.L274Pfs*18 | Frame Shift Ins (INS) | VAF 12/49 reads (24%) | catalogued as rs782340869; called by mutect2, pindel, varscan2
- MOB3A | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100830083; called by muse, mutect2, varscan2
- MOCOS | c.2353A>G p.R785G | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV54342166; called by muse, mutect2, varscan2
- MON2 | c.2476C>T p.H826Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99743748; called by muse, mutect2
- MORC4 | c.2371C>T p.Q791* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99717658; called by muse, mutect2, varscan2
- MOSPD2 | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs1477616051, COSV100996957; called by muse, mutect2, varscan2
- MPHOSPH10 | c.590A>G p.K197R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as rs1252533533, COSV99731320; called by muse, mutect2, varscan2
- MPND | c.972_973del p.E324Dfs*100 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | catalogued as rs1446323974; called by pindel, varscan2
- MPRIP | c.1715T>C p.L572P | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100506161; called by muse, mutect2, varscan2
- MROH9 | c.1253A>G p.Q418R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.591); catalogued as COSV100883089; called by muse, mutect2, varscan2
- MRPL20 | c.442T>C p.Y148H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV61224452; called by muse, mutect2
- MRPS34 | c.651del p.V218Sfs*? | Frame Shift Del (DEL) | VAF 38/110 reads (35%) | catalogued as COSV99169837; called by mutect2, pindel, varscan2
- MTM1 | c.686C>A p.S229* | Nonsense Mutation (SNP) | VAF 19/33 reads (58%) | catalogued as COSV100080738, COSV60336609; called by muse, mutect2, varscan2
- MTSS2 | c.355A>G p.N119D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV100116721; called by muse, mutect2, varscan2
- MUC16 | c.39656G>A p.C13219Y | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs1013061500, COSV101110106; called by muse, mutect2, varscan2
- MUC16 | c.5992C>T p.Q1998* | Nonsense Mutation (SNP) | VAF 35/88 reads (40%) | catalogued as COSV101201883; called by muse, mutect2, varscan2
- MUC16 | c.1486A>G p.S496G | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.329); catalogued as COSV101201884, COSV67467537; called by muse, mutect2, varscan2
- MUC5AC | c.1225T>C p.Y409H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); catalogued as COSV100650714; called by mutect2, varscan2
- MUC5B | c.16919G>A p.C5640Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101500844; called by muse, mutect2, varscan2
- MUSK | c.2513G>A p.C838Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99505222; called by muse, mutect2, varscan2
- MYBL2 | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99406776; called by muse, mutect2, varscan2
- MYC | c.1076A>G p.H359R (on ENST00000377970; = p.H374R on NM_002467.6) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52367783; called by muse, mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO15A | c.4265A>G p.Q1422R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV99234594; called by muse, mutect2, varscan2
- MYO18B | c.2349C>A p.S783R | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV100125361; called by muse, mutect2, varscan2
- MYO3B | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs752855574, COSV100511963; called by muse, mutect2, varscan2
- MYO5A | c.4712A>G p.Y1571C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100698212; called by muse, mutect2, varscan2
- MYO5A | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100698215; called by muse, mutect2, varscan2
- MYO7A | c.1623del p.K542Rfs*80 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | catalogued as COSV68685202; called by mutect2, pindel, varscan2
- MYO9B | c.1859A>G p.Y620C | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101261988; called by muse, mutect2, varscan2
- MYOM1 | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99868599; called by muse, mutect2, varscan2
- MYOM1 | c.287A>G p.H96R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1291026694, COSV99868604; called by muse, mutect2, varscan2
- NALCN | c.3548A>G p.K1183R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV99218054; called by muse, mutect2
- NAP1L2 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs267606508, COSV65172676; called by muse, mutect2, varscan2
- NCBP1 | c.900T>C p.G300= | Splice Region (SNP) | VAF 22/68 reads (32%) | catalogued as COSV100912698; called by muse, mutect2, varscan2
- NCKAP5 | c.4234C>T p.R1412C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs560255831, COSV100494570; called by muse, mutect2, varscan2
- NCOA2 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV101476063; called by muse, mutect2, varscan2
- NCOA2 | c.192C>A p.N64K | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101476064; called by muse, mutect2, varscan2
- NCOR2 | c.3178del p.R1060Vfs*3 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | catalogued as rs749518211, COSV100656528, COSV62300840; called by mutect2, pindel, varscan2
- NDUFA10 | c.604dup p.H202Pfs*25 | Frame Shift Ins (INS) | VAF 7/21 reads (33%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, varscan2
- NDUFAF2 | c.129A>G p.G43= | Splice Region (SNP) | VAF 28/67 reads (42%) | catalogued as COSV99681801; called by muse, mutect2, varscan2
- NEB | c.1787T>G p.M596R | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.417); catalogued as COSV99428456; called by muse, mutect2, varscan2
- NEIL1 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs576861338, COSV99145889; called by muse, mutect2, varscan2
- NEK11 | c.876+1G>C p.X292_splice | Splice Site (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100797929; called by muse, mutect2, varscan2
- NEO1 | c.1289A>G p.H430R | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1230296224, COSV99982882; called by muse, mutect2
- NES | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs1346404820, COSV100958010; called by muse, mutect2, varscan2
- NFATC2 | c.2219C>T p.A740V | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV101044766; called by muse, mutect2
- NFE2L3 | c.1720C>A p.L574I | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV99284068; called by muse, mutect2, varscan2
- NFRKB | c.568C>T p.Q190* (on ENST00000446488 / NM_001143835.2; = p.Q203* on NM_006165.3) | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV100452109; called by muse, mutect2, varscan2
- NKPD1 | c.1390T>C p.C464R | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269416084, COSV100521755; called by muse, mutect2, varscan2
- NLRP3 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as rs202050558, COSV60223862; called by muse, mutect2, varscan2
- NOA1 | c.911A>G p.N304S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99950719; called by muse, mutect2, varscan2
- NOL8 | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1330848713, COSV100694703; called by muse, mutect2, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs759637346; called by mutect2, varscan2
- NOTCH1 | c.3343C>A p.L1115M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53074991; called by muse, mutect2, varscan2
- NOTCH4 | c.4744A>G p.T1582A | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100901120; called by muse, varscan2
- NPC1L1 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV99213639; called by muse, mutect2, varscan2
- NR0B1 | c.1133A>G p.Y378C | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100973554, COSV100973597; called by muse, mutect2, varscan2
- NR0B1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs752705837, COSV66763630; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs774343392; called by mutect2, varscan2
- NRG1 | c.272del p.K91Sfs*24 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs1167519601; called by mutect2, varscan2
1,188 further variants in this file (698 protein-altering or splice-affecting, 443 silent, 47 other) are not listed here.
